Surgical pathology report (de-identified scan), TCGA case TCGA-24-1416, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1416-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

- A. OMENTUM (INCLUDING FS1), BIOPSY
- HIGH GRADE SEROUS CARCINOMA
- B. RIGHT OVARY AND TUBE, RIGHT, EXCISION
- HIGH GRADE SEROUS CARCINOMA INVOLVING THE OVARIAN SURFACE AND PARENCHYMA (10 CM) AND PERITUBAL SOFT TISSUE
- C. LEFT OVARY AND TUBE, LEFT, EXCISION
- HIGH GRADE SEROUS CARCINOMA INVOLVING OVARIAN SURFACE AND PARENCHYMA (10 CM) AND PERITUBAL SOFT TISSUE
- D. SOFT TISSUE, POSTERIOR PERITONEUM, EXCISION
- HIGH GRADE SEROUS CARCINOMA
- E. SOFT TISSUE, RIGHT URETERAL ENCASEMENT, EXCISION
- HIGH GRADE SEROUS CARCINOMA
- F. SOFT TISSUE, RECTOSIGMOID TUMOR, EXCISION
- HIGH GRADE SEROUS CARCINOMA
- G. UTERUS AND CERVIX, EXCISION
- HIGH GRADE SEROUS CARCINOMA INVOLVING UTERINE SEROSA
- CERVIX, ENDOMETRIUM AND MYOMETRIUM NEGATIVE FOR TUMOR
- H. DIAPHRAGM, BIOPSY
- HIGH GRADE SEROUS CARCINOMA
- I. SOFT TISSUE, PELVIC TUMOR, EXCISION
- HIGH GRADE SEROUS CARCINOMA
- J. OMENTUM, EXCISION
- HIGH GRADE SEROUS CARCINOMA
- K. LIVER, EXCISION
- HIGH GRADE SEROUS CARCINOMA INVOLVING THE HEPATIC CAPSULE
- LIVER PARENCHYMA NEGATIVE FOR TUMOR
- L. "GEROTA FASCIA AND PORTION OF ADRENAL," EXCISION

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

- HIGH GRADE SEROUS CARCINOMA INVOLVING THE LIVER PARENCHYMA
- NO ADRENAL GLAND TUMOR IDENTIFIED

M. DIAPHRAGM, RIGHT, EXCISION

- HIGH GRADE SEROUS CARCINOMA

N. SOFT TISSUE, LEFT PERICOLIC GUTTER, EXCISION

- HIGH GRADE SEROUS CARCINOMA

Intraoperative Consultation:

FS1: Omentum, biopsy

- "Poorly differentiated carcinoma, favor Mullerian."

History:

with ascites and elevated levels of CA125. Operative procedure: Examination under anesthesia, exploratory laparotomy, bilateral salpingo-oophorectomy, total abdominal hysterectomy, tumor debulking, omentectomy,

Specimen(s) Received:

- A: OMENTUM
- B: RIGHT OVARY AND TUBE
- C: LEFT OVARY AND TUBE
- D: POSTERIOR PERITONEUM
- E: RIGHT URETERAL ENCASEMENT
- F: RECTOSIGMOID RECTAL TUMOR
- G: UTERUS, CERVIX, RIGHT TUBE AND OVARY
- H: DIAPHRAGM TUMOR
- I: PELVIC TUMOR
- J: OMENTUM
- K: LIVER METASTASIS
- L: GEROTA FASCIA, PORTION OF ADRENAL
- M: RIGHT DIAPHRAGM
- N: LEFT PERICOLIC GUTTER

Gross Description:

The specimens are received in 14 formalin-filled containers, each labeled " ". The first container is labeled "omental biopsy." It contains an irregular mass of tan-pink soft tissue which is irregular in shape and measures 10 x 5.5

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

x 3.5 cm. The specimen is serially sectioned and a portion is subjected to intraoperative frozen section analysis. The cut surfaces of this mass are solid, pale grey-pink and friable.

The second container is labeled "right adnexa." It contains multiple fragments of tan-pink soft tissue, one of which appears to be a portion of fallopian tube and the remainder appear to be part of an enlarged mass. This single enlarged mass measures 10 x 7 x 7 cm and has accumulative weight of 320 grams. The cut surfaces of this mass are solid, pale yellow to pale pink with areas suggestive of necrosis. Friable tissue is seen protruding beyond the surface of the tumor. The fallopian tube seen separate in the container measures 8 cm in length with an average diameter of 0.8 cm. Sectioning reveals a patent lumen with no gross abnormality. Labeled B1 to B10, representative sections from the mass; B11, fallopian tube.

The third container is labeled "left adnexa." It contains multiple fragments of irregular, tan-yellow soft tissue which appears to be a segment of fallopian tube with an irregular, friable, nodular mass. The fallopian tube measures 7 cm in length with an average diameter of 0.8 cm. The irregular, multinodular, friable mass measures 8 x 5 x 5 cm and weighs 110 grams. The specimen is serially sectioned to reveal a solid, pale yellow to pale pink mass with friable degenerating cut surface. A remnant of the ovarian tissue is seen at the center of this mass. Labeled C1 to C8, representative sections from the ovarian

The fourth container is labeled "posterior peritoneum." It contains an irregular piece of tan-pink soft tissue measuring 2 x 1.5 x 1.3 cm. The specimen is serially sectioned and submitted entirely.

The fifth container is labeled "ureteral encasement." It contains an irregular fragment of tan-pink soft tissue measuring 2 x 2.8 x 1 cm. No tubular structures reminiscent of a ureter is grossly identified. The specimen is serially sectioned to reveal pale white, firm, solid cut surfaces with a hint of a tubular structure encased within. This might represent the ureter. The specimen is submitted entirely. Labeled E1 to E3.

The sixth container is labeled "rectosigmoid rectal tumor." It contains two irregular fragments of tan-brown, soft tissue measuring 5 and 2 cm in greatest dimension. The larger fragment has a sheet-like configuration and serially sectioned to reveal a firm, fibrotic sheet of soft tissue. No grossly identifiable lesions are seen in this fragment. The smaller fragment is serially sectioned to reveal a firm nodule measuring 0.7 cm in greatest dimension with pale grey cut surfaces. Sections from the largest segment labeled F1; smaller fragment entirely submitted, F2.

The seventh container is labeled "uterus and cervix." It consists of a hysterectomy specimen weighing 80 grams and measuring 8 cm from top to bottom, 5 cm from cornu to cornu, and 3.2 cm anterior to posterior. A 0.6 cm rim of the vaginal cuff is seen attached to the ectocervix which is tan-pink and grossly unremarkable. It is difficult to orient the specimen and to determine which surface is anterior or posterior. The uterine corpus shows a friable, pale yellow mass protruding from its surface occupying mainly the lower portion of the uterine segment. The specimen is opened to reveal multiple, tiny, cystic lesions clustered together in the region of the endocervical canal. The endocervical canal leads to an endometrial cavity measuring 3 x 1.5 cm. This endometrial cavity is lined by unremarkable pale red lining. The average endometrial uterine wall thickness is 1.4 cm. No other grossly identifiable lesions are seen. Labeled G1, cervix; G2, cervix diagonally opposite to section G1; G3, uterine wall; G4, uterine wall diagonally opposite to G3; G5, uterine wall with exophytic lesion on the external surface.

The eighth container is labeled "diaphragm tumor." It contains multiple irregular fragments of friable, pale yellow-pale white soft tissue, measuring 5 x 4 x 2 cm in aggregate. Sectioning reveals a solid lesion with pale yellow cut surfaces. Labeled H1.

The ninth container is labeled "pelvic tumor." It contains numerous, irregular, friable fragments of pale yellow, soft tissue measuring 10 x 12 x 5 cm in aggregate with an accumulative weight of 120 grams. Sectioning reveals solid, pale yellow lesion tissue on all cut surfaces. Labeled I1.

The tenth container is labeled "omentum." It contains multiple fragments of fibroadipose tissue measuring 20 x 15 x 3 cm. Multiple areas of firm, nodular lesions are identified within. These range in size from < 0.2 cm to 8 cm in greatest dimension. Sectioning reveals pale pink to pale yellow cut surfaces.

The eleventh container is labeled "liver metastases." It contains a disc-shaped fragment of tan-brown soft tissue measuring 5 x 4 x 0.8 cm. The specimen is serially sectioned to reveal a band-like, solid, lesional tissue with pale white cut surfaces. This band of pale white tissue is compressed between two layers of tan-brown soft tissue. Labeled K1 to K2.

The twelfth container is labeled "Gerota's fascia, portion of adrenal." It contains a solitary, irregular fragment of

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

tan-brown soft tissue measuring 7 x 6 x 2.6 cm. There is no definitive evidence of adrenal gland on gross examination after serial sectioning. There is some yellow area seen as a hemorrhagic mass adherent to the surface of this irregular fragment and measures 3 x 3 x 1 cm. The remainder of the specimen shows friable, pale white to pale yellow, solid lesional tissue. Labeled L1 and L2. Jar 1.

The thirteenth container is labeled "right diaphragm." It contains numerous, irregular fragments of tan-brown tissue showing friable, lesional tissue with pale white cut surface throughout the specimen. The specimen has an accumulative measurement of 8 x 8 x 4 cm in aggregate. [REDACTED]

The fourteenth container is labeled "left pericolic gutter." It contains a sheet-like fragment of tan-brown soft tissue measuring 8 x 5 x 1.5 cm. Multiple small nodules are seen that is along the sheet-like fragment. These range in size from 0.3 to 0.8 cm. Labeled N1. Jar 1.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3), high grade

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site is classified as distant metastases (M1): serous carcinoma present within the liver parenchyma

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is pT3c/NX/M1

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 4a82abfd-3c89-45ca-bc54-b948afeff249 (TCGA-24-1416.C5A7B8B5-65B5-47D0-84DC-882024042A6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).